Gene-level copy-number profile of tumor specimen MP2PRT-PAVHCS-TMP1-A from MP2PRT case MP2PRT-PAVHCS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,262 days).
Specimen MP2PRT-PAVHCS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71a0993b-212a-466c-8ace-2e34ffe1cf9e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVHCS-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/380a274e-4d67-4e79-9e75-f17e05182ae8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 684; copy number 2: 31,124; copy number 3: 23,997; copy number 4: 2,563; copy number 5: 2; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr22:18,178,038–18,530,573, 12 genes: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,855,621–18,894,407, 3 genes (within-gene range 0–2): BCRP7, FAM230F, AC008103.1.
- chr22:22,168,289–22,230,469, 11 genes: AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:14,680,604–14,706,597, 2 genes, copy number 5: VN1R74P, GTF2IP8.
- chr21:8,680,538–8,680,934, 1 gene, copy number 6: CR381572.2.

Autosomal genes at a single copy (total copy number 1): 684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
